Gene-level copy-number profile of tumor specimen TCGA-D7-6817-01A from TCGA case TCGA-D7-6817, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 63.4 years (23,142 days).
Specimen TCGA-D7-6817-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.b8366d33-b9af-49ce-9675-4d81d75f75bb.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D7-6817-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f7023186-d123-405f-aa58-8ca67d988b5b

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 356; copy number 2: 21,346; copy number 3: 24,652; copy number 4: 9,675; copy number 5: 2,835; copy number 6: 76; copy number 7: 121; copy number 8: 33; copy number 9: 109; copy number 10: 63; copy number 11: 105; copy number 12: 18; copy number 13: 27; copy number 16: 164; copy number 18: 11; copy number 19: 203; copy number 21: 16.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D7-6817-01A-11D-1881-01): tumor purity 0.44, ploidy 2.99, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 870 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:7,951,263–11,263,557, 84 genes, copy number 9 (within-gene range 1–9) (broad region; genes not listed).
- chr3:11,290,406–11,290,663, 1 gene, copy number 9: AC083855.1.
- chr3:11,952,788–12,885,211, 24 genes, copy number 9: RN7SL147P, SYN2, ACTG1P12, TIMP4, MTCO1P5, GSTM5P1, PPARG, AC091492.1, TSEN2, RNA5SP123, RNU6-377P, MKRN2OS, MKRN2, Metazoa_SRP, RAF1, CRIP1P1, TMEM40, KRT18P17, CAND2, AC034198.2, RPL32, SNORA7A, AC034198.1, LINC02022.
- chr3:16,265,160–18,444,817, 25 genes, copy number 7–18 (within-gene range 3–18): OXNAD1, AC090953.1, RFTN1, AC090948.1, AC090948.2, AC090948.3, AC090948.4, AC010727.1, LINC00690, AC010139.1, DAZL, AC091493.1, CDYLP1, PLCL2, MIR3714, PLCL2-AS1, AC090644.1, TBC1D5, AC090960.1, AC140076.1, RNU7-10P, AC104451.1, AC104451.2, AC104297.1, PDCL3P3.
- chr12:19,941,521–34,249,958, 269 genes, copy number 11–16 (broad region; genes not listed).
- chr12:41,658,676–47,420,192, 96 genes, copy number 8–10 (broad region; genes not listed).
- chr12:62,393,607–73,208,317, 221 genes, copy number 12–19 (within-gene range 3–19) (broad region; genes not listed).
- chr20:42,072,752–44,434,596, 43 genes, copy number 13–21 (within-gene range 3–21): PTPRT, AL035666.1, AL031656.1, PTPRT-AS1, RN7SKP100, AL021395.1, RN7SL666P, PPIAP21, AL021395.2, AL031681.1, RNU6-743P, EIF4EBP2P1, Y_RNA, SRSF6, AL031681.2, RNU6-1251P, L3MBTL1, Z98752.2, Z98752.3, Z98752.1, SGK2, Z98752.4, IFT52, RPL27AP, MYBL2, GTSF1L, RNU6-639P, LINC01728, TOX2, RN7SL443P, JPH2, AL035447.1, OSER1, OSER1-DT, GDAP1L1, FITM2, R3HDML, Y_RNA, AL117382.1, HNF4A, HNF4A-AS1, AL117382.2, MIR3646.
- chr20:62,596,732–64,313,132, 107 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 356. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
